Somatic mutation profile of tumor specimen MP2PRT-PAPZJV-TMP1-A (aliquot MP2PRT-PAPZJV-TMP1-A-1-0-D-A83B-36) from MP2PRT case MP2PRT-PAPZJV, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.2 years (1,186 days).
Specimen MP2PRT-PAPZJV-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9b4b2948-2f58-486d-99d4-742680c2d098.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPZJV-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPZJV-NB1-A-1-0-D-A83B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9ff3406c-cfd1-4ec6-ab84-0504b91bd094

The open-access MAF lists 24 somatic variants for this specimen: 16 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 7, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EPHB4 | c.1736G>A p.G579E | Missense Mutation (SNP) | VAF 82/201 reads (41%) | SIFT tolerated (1); PolyPhen possibly damaging (0.656); catalogued as rs563114834; called by muse, varscan2
- HNRNPA2B1 | c.185G>C p.R62T (on ENST00000354667 / NM_031243.3; = p.R50T on NM_002137.4) | Missense Mutation (SNP) | VAF 80/232 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV61157984; called by muse, mutect2, varscan2
- HPS3 | c.956C>G p.P319R | Missense Mutation (SNP) | VAF 59/185 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs944688815; called by muse, mutect2, varscan2
- JAKMIP1 | c.904C>T p.R302W | Missense Mutation (SNP) | VAF 74/189 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.736); catalogued as rs372443818; called by muse, mutect2, varscan2
- PKD2L2 | c.1719G>C p.E573D | Missense Mutation (SNP) | VAF 76/216 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.346); catalogued as COSV50368238; called by muse, mutect2, varscan2
- RPL34 | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 66/168 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs374094656; called by muse, mutect2, varscan2
- ADGRB3 | c.1298G>A p.G433E | Missense Mutation (SNP) | VAF 135/338 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- C3orf20 | c.2557G>C p.D853H | Missense Mutation (SNP) | VAF 106/265 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- CALCRL | c.983C>T p.S328F | Missense Mutation (SNP) | VAF 30/249 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DYNC2H1 | c.12286G>T p.A4096S | Missense Mutation (SNP) | VAF 141/308 reads (46%) | SIFT tolerated (0.58); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- EOMES | c.1021G>A p.D341N | Missense Mutation (SNP) | VAF 28/240 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- HYDIN | c.8284G>A p.E2762K | Missense Mutation (SNP) | VAF 47/175 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- INTS6L | c.262C>G p.L88V | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- ITPR3 | c.7677C>G p.I2559M | Missense Mutation (SNP) | VAF 87/253 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- OR10A4 | c.881G>T p.R294M | Missense Mutation (SNP) | VAF 105/274 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- PTPRB | c.3918C>G p.F1306L | Missense Mutation (SNP) | VAF 125/344 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.654); called by muse, mutect2, varscan2
- AFF3 | c.426G>A p.K142= | Silent (SNP) | VAF 34/332 reads (10%) | catalogued as rs1140121; called by muse, mutect2, varscan2
- ARFGEF2 | c.4398C>T p.V1466= | Silent (SNP) | VAF 96/268 reads (36%) | called by muse, mutect2, varscan2
- DST | c.4597C>T p.L1533= (on ENST00000361203 / NM_001374722.1; = p.L1207= on NM_015548.5) | Silent (SNP) | VAF 19/230 reads (8%) | called by muse, mutect2
- GNAI2 | c.57C>T p.I19= | Silent (SNP) | VAF 142/359 reads (40%) | called by muse, mutect2, varscan2
- GPT2 | c.1281C>T p.V427= | Silent (SNP) | VAF 115/277 reads (42%) | catalogued as COSV60839383; called by muse, mutect2, varscan2
- MKX | c.150C>A p.P50= | Silent (SNP) | VAF 168/452 reads (37%) | called by muse, mutect2, varscan2
- PHF14 | c.2067C>T p.I689= | Silent (SNP) | VAF 56/154 reads (36%) | called by muse, mutect2, varscan2
- LARS2 | c.*245C>T | 3'UTR (SNP) | VAF 77/220 reads (35%) | called by muse, mutect2, varscan2
